Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7328, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7328-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT AND LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN 9 LYMPH NODES (0/9).

PART 2: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE 4 +3=7 WITH A TERTIARY 5 COMPONENT OF APPROXIMATELY 3%.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS EVIDENCE OF ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION OF RIGHT ANTERIOR BASE (SLIDE 2Q), RIGHT POSTERIOR MID (SLIDES 2AA, 2BB) AND RIGHT POSTERIOR BASE (SLIDES 2CC, 2DD).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- L. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 6.5
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	43gm
TUMOR SIZE:	Maximum dimension: 2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	9
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 8992a5f3-e959-4fe2-b809-c787d341103f (TCGA-EJ-7328.30C9C833-AE7E-46DE-951C-A488DF1D723A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).